Gene-level copy-number profile of tumor specimen C3N-02425-01 (profiled together with C3N-02425-02) from CPTAC case C3N-02425, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 61.2 years (22,361 days).
Specimen C3N-02425-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8c5bd07-a070-422d-a14f-907377e92b56.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02425-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/4b2c0323-80af-4e76-bdc4-7c64f4e3f116

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,409; copy number 2: 20,897; copy number 3: 22,181; copy number 4: 13,456; copy number 5: 376; copy number 6: 145; copy number 7: 24; copy number 8: 220; copy number 9: 46; copy number 10: 63; copy number 13: 12; copy number 15: 3; copy number 18: 14; copy number 22: 1; copy number 24: 49; copy number 30: 9; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 963 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:101,479,390–123,073,481, 366 genes, copy number 5–9 (broad region; genes not listed).
- chr2:169,577,371–169,641,406, 2 genes, copy number 10: AC093899.1, PPIG.
- chr2:169,790,093–173,431,812, 59 genes, copy number 10: CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1.
- chr2:173,705,948–179,050,086, 131 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:179,001,756–181,930,738, 31 genes, copy number 6–10: RPS6P2, SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22, AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2.
- chr6:40,713,411–44,553,281, 144 genes, copy number 8 (broad region; genes not listed).
- chr6:60,281,444–65,707,226, 38 genes, copy number 5–8 (within-gene range 4–8): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr8:7,926,337–8,032,305, 10 genes, copy number 5: ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P.
- chr11:31,369,840–31,509,645, 2 genes, copy number 5: DNAJC24, IMMP1L.
- chr17:31,303,770–31,321,749, 3 genes, copy number 8 (within-gene range 2–8): EVI2B, AC134669.1, EVI2A.
- chr17:31,391,675–32,877,177, 64 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr18:3,406,342–3,478,978, 4 genes, copy number 6: RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,885,353–3,885,432, 1 gene, copy number 6 (within-gene range 4–6): MIR6718.
- chr18:24,489,375–32,470,882, 108 genes, copy number 7–31 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
